Gene-level copy-number profile of tumor specimen CDDP-ABL8-TTP1-C from CDDP_EAGLE case CDDP-ABL8, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60 years.
Specimen CDDP-ABL8-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2917968b-1220-4df7-87fd-85534b84b996.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABL8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/ea8ec57d-bf9b-45d2-b412-9282a848e194

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 171; copy number 1: 1; copy number 2: 17,674; copy number 3: 797; copy number 4: 29,552; copy number 5: 674; copy number 6: 6,458; copy number 7: 71; copy number 8: 3,077; copy number 9: 37; copy number 10: 394; copy number 14: 3.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:165,279,664–165,989,615, 7 genes: C6orf118, PDE10A, RNA5SP226, RNU6-730P, AL590302.2, AL590302.1, LINC00602.
- chr11:16,777,297–17,014,414, 3 genes (within-gene range 0–2): PLEKHA7, RN7SKP90, AC116533.1.
- chr16:32,185,624–32,202,822, 4 genes (within-gene range 0–4): AC133485.6, AC133485.5, AC133485.4, ABHD17AP8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 434 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:51,716,657–53,366,209, 9 genes, copy number 10–14: RN7SL292P, AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P.
- chr7:114,922,359–117,323,152, 52 genes, copy number 10: MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr7:137,227,341–143,184,435, 214 genes, copy number 9–10 (broad region; genes not listed).
- chr9:78,589,158–78,589,539, 1 gene, copy number 9: AL592221.1.
- chr12:50,392,383–51,392,867, 34 genes, copy number 9 (within-gene range 2–9): LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP, BIN2, CELA1, GALNT6.
- chr12:61,708,259–64,507,329, 61 genes, copy number 10 (broad region; genes not listed).
- chr12:64,507,166–64,575,741, 2 genes, copy number 9–10: AC078962.2, SNORD83.
- chr12:67,929,235–70,243,379, 61 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
